Somatic mutation profile of tumor specimen TARGET-30-PALAKM-01A (aliquot TARGET-30-PALAKM-01A-01W) from TARGET case TARGET-30-PALAKM, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 4.8 years (1,758 days).
Specimen TARGET-30-PALAKM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0776a722-d0c4-4105-95ff-d8785a1460ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALAKM-10A (Blood Derived Normal), aliquot TARGET-30-PALAKM-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/154908aa-a6ea-43ad-aa76-d6075b507a48

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 8, Nonsense Mutation 2, Frame Shift Ins 2, Intron 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.3005T>C p.V1002A | Missense Mutation (SNP) | VAF 142/989 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as rs766075655, COSV61257624; called by muse, mutect2, varscan2
- ATIC | c.442C>G p.P148A | Missense Mutation (SNP) | VAF 116/312 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV52692268; called by muse, mutect2, varscan2
- CD1A | c.393G>T p.L131F | Missense Mutation (SNP) | VAF 201/661 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as COSV56860735; called by muse, mutect2, varscan2
- CFI | c.1741T>A p.Y581N | Missense Mutation (SNP) | VAF 136/219 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV67098056; called by muse, mutect2, varscan2
- DHRS4 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs779512774; called by mutect2, varscan2
- DMXL1 | c.2990T>G p.V997G | Missense Mutation (SNP) | VAF 117/300 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV60706464; called by muse, mutect2, varscan2
- DRC7 | c.764G>T p.C255F | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.64); PolyPhen benign (0.025); catalogued as COSV61053506; called by muse, mutect2, varscan2
- GTPBP10 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 59/308 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55986522, COSV99746404; called by mutect2, varscan2
- ING2 | c.412G>C p.A138P | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV56563868; called by muse, mutect2, varscan2
- MAN2A1 | c.2560A>T p.I854L | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV54847316; called by muse, mutect2, varscan2
- MASP1 | c.1582G>T p.E528* | Nonsense Mutation (SNP) | VAF 72/854 reads (8%) | catalogued as COSV61829664; called by muse, mutect2
- MED13 | c.3424C>G p.L1142V | Missense Mutation (SNP) | VAF 138/681 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV67262373; called by muse, mutect2, varscan2
- MYH1 | c.3562C>A p.Q1188K | Missense Mutation (SNP) | VAF 107/275 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV56844950, COSV99875781; called by muse, mutect2, varscan2
- OR2T6 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 22/73 reads (30%) | catalogued as COSV63215885; called by muse, mutect2, varscan2
- PTGER4 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs751358283, COSV56720275; called by muse, mutect2, varscan2
- TKFC | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs376589112, COSV67524077; called by mutect2, varscan2
- CYP11A1 | c.1105dup p.T369Nfs*33 | Frame Shift Ins (INS) | VAF 30/94 reads (32%) | called by mutect2, pindel, varscan2
- IL18RAP | c.1762dup p.E588Gfs*10 | Frame Shift Ins (INS) | VAF 86/258 reads (33%) | called by mutect2, pindel, varscan2
- NEU2 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); called by mutect2, varscan2
- PPP3CA | c.539A>G p.D180G | Missense Mutation (SNP) | VAF 36/464 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.386); called by muse, mutect2
- RAB34 | c.212+2_212+8del p.X71_splice | Splice Site (DEL) | VAF 11/22 reads (50%) | called by mutect2, varscan2
- ANKRD17 | c.5691T>A p.A1897= | Silent (SNP) | VAF 20/284 reads (7%) | called by muse, mutect2
- ARHGDIA | c.561C>T p.T187= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as rs760287781; called by mutect2, varscan2
- ITGAE | c.1884C>T p.S628= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV53990427; called by mutect2, varscan2
- KSR2 | c.1257C>T p.Y419= | Silent (SNP) | VAF 35/60 reads (58%) | catalogued as COSV56668072; called by mutect2, varscan2
- ST8SIA4 | c.870A>G p.R290= | Silent (SNP) | VAF 45/115 reads (39%) | catalogued as rs759666666, COSV51507210; called by muse, mutect2, varscan2
- TBC1D9B | c.543C>T p.H181= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV62281311; called by mutect2, varscan2
- WWC2 | c.687A>G p.R229= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV66712780; called by muse, mutect2, varscan2
- ZNF536 | c.1002C>T p.P334= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs770057737, COSV62833729; called by mutect2, varscan2
- AGBL4 | c.1267+27G>A | Intron (SNP) | VAF 15/31 reads (48%) | catalogued as rs761834505; called by muse, mutect2, varscan2
- SNORD116-25 | n.64T>G | RNA (SNP) | VAF 122/336 reads (36%) | called by muse, mutect2, varscan2
